Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3973, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3973-01A (Primary Tumor).

Diagnosis (diagnoses):

Colon resection sample with a moderately differentiated adenocarcinoma of the colorectal type, measuring a max of 3 cm in diameter, with infiltration of the pericolic fatty tissue, circumscribed penetration of the covering serosa and three local lymph node metastases. Tumor-free colon resection margins. Tumor-free mesenteric resection margin.

The tumor stage is: pT4, pN1 (3/21) pM1 (clinical liver and lung metastasis) L0, V0; clinically G2

Source: NCI Genomic Data Commons file fe40fd05-06d6-452b-b9ca-5a4fcc55be1f (TCGA-AA-3973.9E835A08-C992-405B-A4AA-BE4C570A695C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).